Gene-level copy-number profile of tumor specimen TCGA-OR-A5KU-01A from TCGA case TCGA-OR-A5KU, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 37.1 years (13,559 days).
Specimen TCGA-OR-A5KU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.3a9f554e-420f-422a-b377-9ef347a926cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5KU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9553740-2c9e-49e9-bc10-dab1c3624252

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 1,391; copy number 2: 2; copy number 3: 30,841; copy number 4: 6; copy number 5: 757; copy number 6: 10,528; copy number 7: 211; copy number 8: 12,950; copy number 10: 745; copy number 11: 2,275.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5KU-01A-11D-A29H-01): tumor purity 0.82, ploidy 2.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:100,675,930–101,077,910, 114 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 16,181 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–180,759,038, 2,473 genes, copy number 7–8 (broad region; genes not listed).
- chr4:181,820,019–190,092,279, 176 genes, copy number 8 (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,985 genes, copy number 7–11 (broad region; genes not listed).
- chr12:66,767–133,214,832, 3,050 genes, copy number 8 (broad region; genes not listed).
- chr16:11,555–35,912,516, 1,419 genes, copy number 8 (broad region; genes not listed).
- chr17:54,951,902–55,561,577, 12 genes, copy number 8 (within-gene range 3–8): COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P.
- chr17:56,368,063–83,095,122, 882 genes, copy number 8 (broad region; genes not listed).
- chr19:94,062–58,605,223, 2,981 genes, copy number 8 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 8 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,391. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
